Somatic mutation profile of tumor specimen TCGA-CZ-4859-01A (aliquot TCGA-CZ-4859-01A-02D-1429-08) from TCGA case TCGA-CZ-4859, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 59.8 years (21,842 days).
Specimen TCGA-CZ-4859-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 66008de9-bab8-4407-af9d-a1842302c310.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CZ-4859-11A (Solid Tissue Normal), aliquot TCGA-CZ-4859-11A-01D-1429-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cb337421-962f-4bb9-81eb-4786c86fffe6

The open-access MAF lists 116 somatic variants for this specimen: 94 protein-altering or splice-affecting, 21 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 66, Silent 21, Frame Shift Del 8, Frame Shift Ins 6, Nonsense Mutation 5, Splice Site 4, In Frame Del 3, Translation Start Site 1, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.14905G>A p.D4969N | Missense Mutation (SNP) | VAF 42/400 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as COSV68949274; called by muse, mutect2
- ABCD3 | c.677G>A p.G226E | Missense Mutation (SNP) | VAF 40/131 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59867168; called by muse, mutect2, varscan2
- AIFM3 | c.1109G>T p.R370M | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.103); catalogued as COSV59001801; called by muse, mutect2, varscan2
- ALDH1A2 | c.846A>T p.R282S | Missense Mutation (SNP) | VAF 86/199 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV51086976, COSV99991065; called by muse, mutect2, varscan2
- APLP2 | c.1507G>C p.D503H | Missense Mutation (SNP) | VAF 95/278 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1316846592, COSV53842706; called by muse, mutect2, varscan2
- APPL2 | c.1190C>T p.A397V | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.358); catalogued as COSV51592320; called by muse, mutect2, varscan2
- ATP9B | c.306G>A p.W102* | Nonsense Mutation (SNP) | VAF 14/153 reads (9%) | catalogued as COSV56957221; called by muse, mutect2
- B3GALT4 | c.870G>T p.E290D | Missense Mutation (SNP) | VAF 51/186 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65851987; called by muse, mutect2, varscan2
- BRWD3 | c.3181G>A p.A1061T | Missense Mutation (SNP) | VAF 263/512 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64751582; called by muse, mutect2, varscan2
- C17orf75 | c.941T>C p.L314P | Missense Mutation (SNP) | VAF 29/257 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV56753435; called by muse, mutect2, varscan2
- CHAF1B | c.1463C>G p.T488R | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV58441014; called by muse, mutect2, varscan2
- CLK2 | c.487+1del p.X163_splice (on ENST00000368361 / NM_001294339.2; = p.X162_splice on NM_003993.4) | Splice Site (DEL) | VAF 70/150 reads (47%) | catalogued as COSV62878042; called by mutect2, pindel, varscan2
- COLGALT2 | c.609G>C p.W203C | Missense Mutation (SNP) | VAF 26/525 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62730193; called by muse, mutect2
- COX6B2 | c.106T>G p.F36V | Missense Mutation (SNP) | VAF 30/400 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV100427759; called by muse, mutect2
- CRYBG1 | c.4819A>G p.I1607V | Missense Mutation (SNP) | VAF 10/139 reads (7%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.876); catalogued as rs573858590, COSV64811363, COSV64813528; called by muse, mutect2
- CYP27C1 | c.35C>G p.P12R | Missense Mutation (SNP) | VAF 208/426 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58867567; called by muse, mutect2, varscan2
- CYP4A11 | c.1145T>C p.L382P | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs772865981, COSV60224715; called by muse, mutect2, varscan2
- DNAJC15 | c.309A>T p.V103= | Splice Region (SNP) | VAF 40/97 reads (41%) | catalogued as COSV64872741; called by muse, mutect2, varscan2
- DOCK2 | c.4580T>A p.L1527H | Missense Mutation (SNP) | VAF 21/280 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56956033; called by muse, mutect2
- EME2 | c.652G>T p.E218* | Nonsense Mutation (SNP) | VAF 9/46 reads (20%) | catalogued as COSV51602009; called by muse, mutect2, varscan2
- ENPP7 | c.370G>A p.V124M | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.024); catalogued as rs145931726; called by muse, varscan2
- EP300 | c.6643C>A p.Q2215K | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.056); catalogued as COSV54331285, COSV54339679; called by muse, mutect2, varscan2
- FAT1 | c.9086C>T p.S3029L | Missense Mutation (SNP) | VAF 56/145 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.17); catalogued as COSV71673354, COSV71675262; called by muse, mutect2, varscan2
- GAS2 | c.267+1G>C p.X89_splice | Splice Site (SNP) | VAF 56/132 reads (42%) | catalogued as COSV53410304; called by muse, mutect2, varscan2
- IFT172 | c.681C>A p.H227Q | Missense Mutation (SNP) | VAF 65/105 reads (62%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as COSV53136850; called by muse, mutect2, varscan2
- IMPG1 | c.980C>T p.S327F | Missense Mutation (SNP) | VAF 83/225 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.33); catalogued as COSV64060039; called by muse, mutect2, varscan2
- INPP4A | c.717del p.D239Efs*25 | Frame Shift Del (DEL) | VAF 47/217 reads (22%) | catalogued as COSV50795518; called by mutect2, pindel, varscan2
- IST1 | c.1097A>G p.D366G (on ENST00000535424 / NM_001270976.1; = p.M352V on NM_014761.4) | Missense Mutation (SNP) | VAF 170/664 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.842); catalogued as COSV58665186; called by muse, mutect2, varscan2
- ITM2B | c.374_379del p.E125_E126del | In Frame Del (DEL) | VAF 43/129 reads (33%) | catalogued as rs751018650; called by mutect2, varscan2
- JAK1 | c.243T>A p.Y81* | Nonsense Mutation (SNP) | VAF 10/105 reads (10%) | catalogued as COSV61094476; called by muse, mutect2
- KIF18A | c.2536G>A p.V846I | Missense Mutation (SNP) | VAF 53/133 reads (40%) | SIFT tolerated (0.49); PolyPhen benign (0.017); catalogued as rs748687672, COSV54185609; called by muse, mutect2, varscan2
- KPRP | c.765C>A p.C255* | Nonsense Mutation (SNP) | VAF 86/161 reads (53%) | catalogued as COSV64222428; called by muse, mutect2, varscan2
- LIMD1 | c.973G>C p.V325L | Missense Mutation (SNP) | VAF 63/107 reads (59%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV56269007; called by muse, mutect2, varscan2
- LMAN1L | c.364G>A p.G122S | Missense Mutation (SNP) | VAF 25/200 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.627); catalogued as COSV59002848; called by muse, mutect2, varscan2
- LRP1 | c.9009T>A p.Y3003* | Nonsense Mutation (SNP) | VAF 20/161 reads (12%) | catalogued as COSV54519667; called by muse, mutect2, varscan2
- MAPT | c.1343A>G p.Q448R (on ENST00000262410 / NM_001377265.1; = p.Q373R on NM_016835.4) | Missense Mutation (SNP) | VAF 109/313 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.23); catalogued as COSV52244622; called by muse, mutect2, varscan2
- MKKS | c.433A>G p.S145G | Missense Mutation (SNP) | VAF 69/168 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0.031); catalogued as COSV61399361; called by muse, mutect2, varscan2
- MYOC | c.886C>T p.R296C | Missense Mutation (SNP) | VAF 55/205 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs759114694, CM092549, COSV50676546; called by muse, mutect2, varscan2
- NBR1 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 58/154 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs536512807, COSV57834161; called by muse, mutect2, varscan2
- NCOA6 | c.4331T>C p.V1444A | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV62866051; called by muse, mutect2, varscan2
- ORMDL3 | c.212C>A p.P71H | Missense Mutation (SNP) | VAF 107/349 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58346130, COSV58346285; called by muse, mutect2, varscan2
- PAN3 | c.586C>G p.L196V | Missense Mutation (SNP) | VAF 61/237 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.969); catalogued as COSV66710177; called by muse, mutect2, varscan2
- PCNX1 | c.1625T>A p.V542D | Missense Mutation (SNP) | VAF 69/229 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.723); catalogued as COSV53098540; called by muse, mutect2, varscan2
- PIAS1 | c.964A>G p.S322G | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.341); catalogued as COSV51035119; called by muse, mutect2, varscan2
- PLCE1 | c.923A>G p.D308G | Missense Mutation (SNP) | VAF 118/312 reads (38%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs773934458, COSV53362490; called by muse, mutect2, varscan2
- PLXNA3 | c.4331A>T p.K1444M | Missense Mutation (SNP) | VAF 14/260 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63754908; called by muse, mutect2
- PRIM2 | c.182T>A p.V61E | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV51424882; called by muse, mutect2, varscan2
- PRODH2 | c.464C>A p.S155Y (on ENST00000301175; = p.S79Y on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV56560991; called by muse, mutect2, varscan2
- RAB36 | c.737C>G p.A246G | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as COSV54075812; called by muse, mutect2, varscan2
- RALY | c.445C>G p.R149G (on ENST00000246194 / NM_016732.3; = p.R133G on NM_007367.4) | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55782782; called by muse, mutect2, varscan2
- RFX1 | c.1078G>C p.V360L | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.102); catalogued as COSV54332087; called by muse, mutect2, varscan2
- RPRD2 | c.3397A>G p.T1133A | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.011); catalogued as COSV64822197; called by muse, mutect2, varscan2
- RUNDC3B | c.1269G>A p.M423I | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs772748384, COSV56695400; called by muse, mutect2, varscan2
- SEL1L2 | c.1910A>T p.E637V | Missense Mutation (SNP) | VAF 40/153 reads (26%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.446); catalogued as rs765561040, COSV53155499; called by muse, mutect2, varscan2
- SIGLEC1 | c.3578G>A p.C1193Y | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52468729; called by muse, mutect2, varscan2
- SLC25A28 | c.461A>C p.K154T | Missense Mutation (SNP) | VAF 42/113 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0.405); catalogued as COSV65125591; called by muse, mutect2, varscan2
- SLC3A1 | c.431-2A>G p.X144_splice | Splice Site (SNP) | VAF 21/99 reads (21%) | catalogued as COSV53223993; called by muse, mutect2, varscan2
- SLC4A5 | c.1652A>T p.Q551L | Missense Mutation (SNP) | VAF 50/95 reads (53%) | SIFT tolerated (1); PolyPhen probably damaging (0.999); catalogued as COSV61030729; called by muse, mutect2, varscan2
- SOWAHD | c.755G>T p.G252V | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.021); catalogued as COSV59649835; called by muse, mutect2
- SPEN | c.7577A>C p.D2526A | Missense Mutation (SNP) | VAF 146/448 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV65365376; called by muse, mutect2, varscan2
- STAG2 | c.934A>C p.I312L | Missense Mutation (SNP) | VAF 91/460 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.034); catalogued as COSV54366630; called by muse, mutect2, varscan2
- STIL | c.748T>A p.S250T | Missense Mutation (SNP) | VAF 9/167 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV54552217; called by muse, mutect2
- STS | c.68A>G p.N23S | Missense Mutation (SNP) | VAF 10/208 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV54270418; called by muse, mutect2
- SUZ12 | c.1013T>A p.L338H | Missense Mutation (SNP) | VAF 107/252 reads (42%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.96); catalogued as COSV59501999; called by muse, mutect2, varscan2
- SYNE2 | c.10331C>T p.S3444L | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs372338837, COSV59939872; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TARBP1 | c.4064G>A p.C1355Y | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.753); catalogued as COSV50195094; called by muse, mutect2, varscan2
- TEX13A | c.769T>G p.Y257D | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as COSV61170352; called by muse, mutect2, varscan2
- TMPRSS11A | c.977A>G p.D326G | Missense Mutation (SNP) | VAF 116/292 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0.087); catalogued as rs918901564, COSV58360054; called by muse, mutect2
- TNIK | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 17/148 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV52689993; called by muse, mutect2, varscan2
- TRAFD1 | c.56A>G p.E19G | Missense Mutation (SNP) | VAF 69/227 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.364); catalogued as COSV57505515; called by muse, mutect2, varscan2
- TTN | c.71207T>G p.F23736C (on ENST00000591111; = p.F16312C on NM_003319.4) | Missense Mutation (SNP) | VAF 6/184 reads (3%) | PolyPhen probably damaging (0.939); catalogued as COSV60219066; called by muse, mutect2
- TUT1 | c.565G>C p.E189Q | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53471230; called by muse, mutect2
- VTN | c.508G>C p.G170R | Missense Mutation (SNP) | VAF 37/147 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56874393; called by muse, mutect2, varscan2
- WDR70 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 86/292 reads (29%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.38); catalogued as COSV54279243; called by muse, mutect2, varscan2
- ZAP70 | c.1124C>T p.T375M | Missense Mutation (SNP) | VAF 16/270 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as rs776066014, COSV53855925; called by muse, mutect2
- ZIC4 | c.292T>C p.Y98H | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV67173166; called by muse, mutect2, varscan2
- ZNF556 | c.328G>A p.V110M | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.045); catalogued as COSV56913293; called by muse, mutect2
- AASDH | c.1975del p.T659Hfs*9 | Frame Shift Del (DEL) | VAF 125/467 reads (27%) | called by mutect2, pindel, varscan2
- CCDC180 | c.821dup p.N274Kfs*48 | Frame Shift Ins (INS) | VAF 94/351 reads (27%) | called by mutect2, pindel, varscan2
- CEP57L1 | c.691_699del p.M231_S233del | In Frame Del (DEL) | VAF 11/27 reads (41%) | called by mutect2, pindel, varscan2
- CFAP43 | c.3091dup p.Y1031Lfs*2 | Frame Shift Ins (INS) | VAF 23/57 reads (40%) | called by mutect2, varscan2
- CFAP43 | c.3090delinsGT p.Y1031Lfs*2 | Frame Shift Ins (INS) | VAF 22/74 reads (30%) | called by mutect2*, pindel, varscan2*
- ERBB2 | c.1161dup p.N388Qfs*14 | Frame Shift Ins (INS) | VAF 12/47 reads (26%) | called by mutect2, pindel, varscan2
- HLA-DPA1 | c.100+1del p.X34_splice | Splice Site (DEL) | VAF 83/365 reads (23%) | called by mutect2, pindel, varscan2
- LRP1B | c.1441_1442del p.G481Nfs*31 | Frame Shift Del (DEL) | VAF 40/198 reads (20%) | called by mutect2, pindel, varscan2
- MGAM | c.4065del p.W1355Cfs*9 | Frame Shift Del (DEL) | VAF 19/126 reads (15%) | called by mutect2, pindel, varscan2
- NCOA4 | c.1067A>C p.K356T | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- NUP210L | c.3380_3382del p.N1127del | In Frame Del (DEL) | VAF 48/191 reads (25%) | called by mutect2, pindel, varscan2
- PHF10 | c.446del p.L149* | Frame Shift Del (DEL) | VAF 7/71 reads (10%) | called by mutect2, pindel
- RBM34 | c.482_483del p.T161Rfs*23 | Frame Shift Del (DEL) | VAF 57/193 reads (30%) | called by pindel, varscan2
- TMCO3 | c.925_932dup p.N312Qfs*3 | Frame Shift Ins (INS) | VAF 56/180 reads (31%) | called by mutect2, varscan2
- VHL | c.451_452dup p.T152Sfs*8 | Frame Shift Ins (INS) | VAF 107/233 reads (46%) | called by mutect2, pindel, varscan2
- ZBTB48 | c.1141_1153del p.C383Sfs*11 | Frame Shift Del (DEL) | VAF 23/76 reads (30%) | called by mutect2, pindel, varscan2
- ZZEF1 | c.6178del p.S2060Qfs*9 | Frame Shift Del (DEL) | VAF 68/223 reads (30%) | called by mutect2, pindel, varscan2
- ABCB5 | c.2175A>G p.K725= (on ENST00000404938 / NM_001163941.2; = p.K280= on NM_178559.6) | Silent (SNP) | VAF 26/94 reads (28%) | catalogued as COSV51716044; called by muse, mutect2, varscan2
- AGMO | c.636A>G p.E212= | Silent (SNP) | VAF 81/219 reads (37%) | catalogued as COSV61119264; called by muse, mutect2, varscan2
- APOB | c.12618G>A p.G4206= | Silent (SNP) | VAF 116/218 reads (53%) | catalogued as COSV51922888; called by muse, mutect2, varscan2
- BNC1 | c.1623T>C p.S541= | Silent (SNP) | VAF 15/273 reads (5%) | catalogued as COSV61758472; called by muse, mutect2
- CABLES2 | c.390C>T p.S130= | Silent (SNP) | VAF 19/64 reads (30%) | catalogued as COSV54157692; called by muse, mutect2, varscan2
- CSAG1 | c.201C>A p.P67= | Silent (SNP) | VAF 71/281 reads (25%) | catalogued as COSV63400804; called by muse, mutect2, varscan2
- DNAJB11 | c.582C>T p.D194= | Silent (SNP) | VAF 60/162 reads (37%) | catalogued as rs138789127; called by muse, mutect2, varscan2
- FAM155A | c.777C>A p.T259= | Silent (SNP) | VAF 25/205 reads (12%) | catalogued as COSV65576111; called by muse, mutect2, varscan2
- G3BP1 | c.64C>T p.L22= | Silent (SNP) | VAF 69/228 reads (30%) | catalogued as COSV62366599; called by muse, mutect2, varscan2
- IARS1 | c.1596C>T p.S532= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as rs1183508029, COSV65116371; called by muse, mutect2, varscan2
- MAPK8 | c.1152C>T p.I384= | Silent (SNP) | VAF 14/256 reads (5%) | catalogued as COSV64410317; called by muse, mutect2
- MED13 | c.447A>G p.K149= | Silent (SNP) | VAF 59/209 reads (28%) | catalogued as COSV67265575; called by muse, mutect2, varscan2
- NOX4 | c.78T>C p.N26= | Silent (SNP) | VAF 67/167 reads (40%) | catalogued as rs1329489351, COSV54459774; called by muse, mutect2, varscan2
- PCDHGB7 | c.783C>T p.I261= | Silent (SNP) | VAF 30/86 reads (35%) | catalogued as rs767197233, COSV53995247; called by muse, mutect2, varscan2
- POLM | c.1248A>G p.R416= | Silent (SNP) | VAF 47/136 reads (35%) | catalogued as COSV54243354; called by muse, mutect2, varscan2
- PPP1R15B | c.258A>G p.Q86= | Silent (SNP) | VAF 22/323 reads (7%) | catalogued as rs368521809; called by muse, mutect2
- SCN5A | c.1164C>A p.I388= | Silent (SNP) | VAF 36/63 reads (57%) | catalogued as COSV61133630; called by muse, mutect2, varscan2
- SEZ6 | c.1362G>A p.R454= | Silent (SNP) | VAF 66/154 reads (43%) | catalogued as COSV57983187; called by muse, mutect2, varscan2
- SYNE2 | c.10332G>C p.S3444= | Silent (SNP) | VAF 36/112 reads (32%) | catalogued as rs1200933436, COSV59961017, COSV59963235; called by muse, mutect2, varscan2
- TSC2 | c.4296C>G p.A1432= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as rs1555514284, COSV51921517; ClinVar: likely benign; called by muse, mutect2, varscan2
- WDR5B | c.843T>A p.I281= | Silent (SNP) | VAF 114/284 reads (40%) | catalogued as COSV51659042; called by muse, mutect2, varscan2
- MGAM | c.4618+5648A>T | Intron (SNP) | VAF 20/53 reads (38%) | catalogued as COSV101527516, COSV101527808; called by muse, mutect2, varscan2
